Surgical pathology report (de-identified scan), TCGA case TCGA-76-6661, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6661-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-76-6661

FINAL DIAGNOSIS:

1. Right temporal tumor: glioblastoma multiforme, grade IV of IV (WHO scale), see microscopic description, see comment.

Comment:

[REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material.

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a markedly pleomorphic and densely infiltrative proliferation of astrocytes. There are abundant mitoses. There is extensive microvascular proliferation. Both pseudopalisading and non-pseudopalisading necrosis is present. The findings are diagnostic of a glioblastoma multiforme, grade IV of IV (WHO scale).

Frozen Section Diagnosis:

1. Right temporal tumor: high-grade glioma, favor GBM [REDACTED]

Clinical History and Diagnosis:
right temporal tumor

Source of Specimen:

- 1: Right temporal tumor

Gross Description:

- [REDACTED]
1. Right temporal tumor: Received fresh in a specimen container labeled with the patient's name and "#1 right temporal tumor", is 5.5 x 4 x 2 cm aggregate of tan-pink soft and gelatinous tissue. Touch [REDACTED]

[page 2 of 2]
[REDACTED]

preparations are made and a representative section is submitted for frozen section analysis. Additional representative sections are submitted for a total of 6 cassettes.

A. frozen section control

B.-D. additional representative sections of specimen

Histology Laboratory

H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Pathway Her-2/neu (4B5) (Rabbit monoclonal) - Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit. Interpretation follows the manufacturer's recommendation.

3. EGFR (3C6) (Mouse Monoclonal) Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit.

4. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]

[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 8c01d5d1-025b-43f6-ba3b-9d35490cbe10 (TCGA-76-6661.EBDC6747-57B5-4D88-A9CD-9222A7F71129.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).